Somatic mutation profile of tumor specimen 0DQJIU from CCDI case PBCECG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,710 days).
Specimen 0DQJIU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ef333ed-2e03-498a-b4d0-908f9038b232.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQJIH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc007362-e123-4dcc-91d2-adaa8ddf431c

The open-access MAF lists 43 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Intron 4, 3'UTR 1, Splice Region 1, RNA 1, 5'Flank 1, 5'UTR 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.225+2T>C p.X75_splice | Splice Site (SNP) | VAF 24/167 reads (14%) | catalogued as COSV100938184; called by muse, mutect2, varscan2
- NF1 | c.6002G>C p.G2001A (on ENST00000358273 / NM_001042492.3; = p.G1980A on NM_000267.3) | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV100648002; called by muse, mutect2, varscan2
- NSD1 | c.6427C>A p.H2143N | Missense Mutation (SNP) | VAF 45/510 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM052328; called by muse, mutect2
- RMC1 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 67/298 reads (22%) | catalogued as rs754159771; called by muse, mutect2, varscan2
- SBSN | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs1568676285; called by muse, mutect2, varscan2
- ARHGAP31 | c.3550T>G p.S1184A | Missense Mutation (SNP) | VAF 79/324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CBL | c.1143T>G p.C381W | Missense Mutation (SNP) | VAF 141/312 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC9A | c.172T>C p.L58= | Splice Region (SNP) | VAF 47/230 reads (20%) | called by muse, mutect2, varscan2
- CYTH3 | c.512C>G p.A171G | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- E2F4 | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHB6 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 117/647 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOCAD | c.3906T>A p.H1302Q | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- GSE1 | c.509C>G p.P170R | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- HEMK1 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 92/381 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- HIVEP2 | c.6808T>G p.S2270A | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- ING1 | c.1215G>C p.K405N | Missense Mutation (SNP) | VAF 38/401 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITIH2 | c.1424G>T p.R475M | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.973C>G p.H325D | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- MUC16 | c.1753A>T p.T585S | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- NLRP2 | c.2431C>A p.Q811K | Missense Mutation (SNP) | VAF 112/392 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PCDHA10 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 77/604 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PILRB | c.557T>A p.L186Q | Missense Mutation (SNP) | VAF 35/773 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); called by muse, mutect2
- PRCP | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 17/648 reads (3%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- RAMP2 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.085); called by muse, mutect2
- SAMD3 | c.941A>C p.E314A | Missense Mutation (SNP) | VAF 95/415 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SUN1 | c.2042T>C p.F681S (on ENST00000405266 / NM_001367651.1; = p.F561S on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/672 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UBC | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 33/428 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2
- UTRN | c.3653G>T p.C1218F | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DNAI1 | c.1803C>T p.V601= | Silent (SNP) | VAF 20/412 reads (5%) | called by muse, mutect2
- IFI16 | c.417C>T p.P139= | Silent (SNP) | VAF 29/408 reads (7%) | catalogued as rs766639299, COSV55533574; called by muse, mutect2
- INHBA | c.753C>T p.G251= | Silent (SNP) | VAF 52/568 reads (9%) | catalogued as rs776081862, COSV54224528; called by muse, mutect2
- JUND | c.276C>T p.D92= | Silent (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- RBFOX1 | c.75C>T p.Y25= | Silent (SNP) | VAF 100/433 reads (23%) | catalogued as COSV100299328; called by muse, mutect2, varscan2
- SEMA6B | c.2211C>T p.H737= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as rs1170221255; called by muse, mutect2, varscan2
- SETBP1 | c.1119C>T p.S373= | Silent (SNP) | VAF 47/490 reads (10%) | catalogued as rs773249152, COSV99952668; ClinVar: likely benign; called by muse, mutect2, varscan2
- DGKA | c.-81-482G>C | Intron (SNP) | VAF 85/331 reads (26%) | called by muse, mutect2, varscan2
- DNAH3 | c.1700-14T>G | Intron (SNP) | VAF 30/254 reads (12%) | called by muse, mutect2, varscan2
- IL1RL1 | c.970+9T>A | Intron (SNP) | VAF 31/324 reads (10%) | called by muse, mutect2, varscan2
- ITGAM | c.858+25A>G | Intron (SNP) | VAF 15/234 reads (6%) | called by muse, mutect2
- MUC19 | n.11316G>C | RNA (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- PRDM7 | c.-30G>C | 5'UTR (SNP) | VAF 58/263 reads (22%) | called by muse, mutect2, varscan2
- SPSB3 | chr16:1781529 A>G | 5'Flank (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- ZHX1-C8orf76 | c.*52C>T | 3'UTR (SNP) | VAF 32/134 reads (24%) | called by mutect2, varscan2
